Somatic mutation profile of tumor specimen MBCProject_0915_T1_WES (aliquot MBCProject_0915_T1_WES_1) from CMI case MBCProject_0915, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.4 years (15,848 days).
Specimen MBCProject_0915_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dfbeccd-4e54-4d58-a6ab-0b55d4c8fd24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0915_SALIVA (Saliva), aliquot MBCProject_0915_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0481485-fde5-48a4-bab3-7c98fa4221ee

The open-access MAF lists 105 somatic variants for this specimen: 57 protein-altering or splice-affecting, 34 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 34, Nonsense Mutation 6, Intron 5, 5'UTR 4, Splice Site 3, RNA 3, Splice Region 1, In Frame Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALG2 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99445575; called by muse, mutect2, varscan2
- ATM | c.2972T>G p.L991* | Nonsense Mutation (SNP) | VAF 54/166 reads (33%) | catalogued as COSV53743206; called by muse, mutect2, varscan2
- BIRC3 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs200008391, COSV54816536; called by muse, mutect2, varscan2
- DCAF12L1 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 56/654 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs765744357, COSV64422108, COSV64422532; called by muse, mutect2
- DYNC1H1 | c.13452G>C p.E4484D | Missense Mutation (SNP) | VAF 47/819 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV64142126; called by muse, mutect2
- GAS8 | c.1141_1143del p.K381del | In Frame Del (DEL) | VAF 64/620 reads (10%) | catalogued as rs760468250; called by pindel, varscan2
- GNAQ | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54116426; called by muse, mutect2, varscan2
- NCOR1 | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 11/145 reads (8%) | catalogued as COSV51977521; called by muse, mutect2
- NUTM2D | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 24/768 reads (3%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.727); catalogued as rs1326500341; called by muse, mutect2
- PCDHA6 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 26/841 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782671161; called by muse, mutect2
- PRRC2A | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs773615650; called by muse, mutect2, varscan2
- RAB4B | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs769467373, COSV99648302; called by muse, mutect2, varscan2
- RASAL2 | c.2497G>C p.D833H | Missense Mutation (SNP) | VAF 50/749 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV62718212; called by muse, mutect2
- RBM6 | c.3344T>A p.M1115K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1486512281; called by muse, mutect2
- SCARA3 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 51/280 reads (18%) | catalogued as rs764235795, COSV57271624; called by muse, mutect2, varscan2
- SLC7A2 | c.1855G>C p.D619H (on ENST00000494857 / NM_001370338.1; = p.D658H on NM_003046.6) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs747875628, COSV50255358; called by mutect2, varscan2
- SRCAP | c.3155C>T p.S1052L | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52672785, COSV99351818; called by muse, mutect2
- ZBTB10 | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100990142, COSV66948746; called by muse, mutect2
- ZNF560 | c.2284C>G p.H762D | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56871081; called by muse, mutect2
- ADAMTS9 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.231); called by muse, mutect2
- ADCY10 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.388); called by muse, mutect2
- ASXL2 | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- BLVRB | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.133); called by muse, mutect2
- CCDC82 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2
- CEMIP2 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.059); called by muse, mutect2
- CFAP69 | c.1918C>G p.P640A | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTN5 | c.1649T>C p.V550A | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DMPK | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- EFNA1 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 36/944 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.1); called by muse, mutect2
- FGF5 | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 27/577 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- FXR2 | c.930C>A p.N310K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GRAMD2A | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HES1 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1000-7_1001delinsTTTTTTTTT p.X334_splice | Splice Site (ONP) | VAF 6/62 reads (10%) | called by mutect2*, pindel
- HSF2 | c.209T>C p.F70S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL16 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- INHBA | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.273); called by muse, mutect2
- INSRR | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ISLR2 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.011); called by muse, mutect2
- LIMK1 | c.1646A>T p.D549V | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC8B | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MARK4 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 29/321 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MROH1 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.053); called by muse, mutect2
- ORM1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- OTOGL | c.2474C>G p.S825* (on ENST00000547103; = p.S816* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- PIKFYVE | c.1824G>A p.L608= | Splice Region (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- PODXL2 | c.1606-2A>C p.X536_splice | Splice Site (SNP) | VAF 54/413 reads (13%) | called by muse, mutect2, varscan2
- PTN | c.289+1G>A p.X97_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- PTPN6 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 99/742 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- RFXANK | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 33/822 reads (4%) | called by muse, mutect2
- RNF123 | c.3667G>C p.E1223Q | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- RYR2 | c.13240G>A p.E4414K | Missense Mutation (SNP) | VAF 38/556 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.578); called by muse, mutect2
- SPRED3 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TMEM151B | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 165/448 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- ZC3HAV1 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 28/435 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- ZNF480 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG1 | c.1305C>T p.L435= | Silent (SNP) | VAF 48/671 reads (7%) | catalogued as rs751083177; called by muse, mutect2
- AIFM3 | c.1741C>A p.R581= | Silent (SNP) | VAF 18/358 reads (5%) | catalogued as COSV53151195; called by muse, mutect2
- AKR7A2 | c.390G>T p.L130= | Silent (SNP) | VAF 43/523 reads (8%) | called by muse, mutect2
- AMIGO3 | c.477C>T p.L159= | Silent (SNP) | VAF 50/824 reads (6%) | catalogued as COSV57538590, COSV57539341; called by muse, mutect2
- ARHGAP36 | c.1074C>T p.C358= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- ATP4A | c.312G>A p.A104= | Silent (SNP) | VAF 56/434 reads (13%) | catalogued as rs970058720; called by muse, mutect2, varscan2
- BCOR | c.2586C>T p.I862= | Silent (SNP) | VAF 26/374 reads (7%) | called by muse, mutect2
- CRYBG2 | c.2394C>T p.A798= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- FBP1 | c.312C>T p.I104= | Silent (SNP) | VAF 23/386 reads (6%) | called by muse, mutect2
- FOXD4 | c.1050C>T p.P350= | Silent (SNP) | VAF 54/1980 reads (3%) | called by muse, mutect2
- G6PD | c.1356C>T p.F452= | Silent (SNP) | VAF 58/876 reads (7%) | catalogued as rs370808115, COSV63704155; called by muse, mutect2
- GINS2 | c.75G>A p.K25= | Silent (SNP) | VAF 60/474 reads (13%) | called by muse, mutect2, varscan2
- H1-2 | c.540G>A p.A180= | Silent (SNP) | VAF 73/698 reads (10%) | catalogued as rs773564861, COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2, varscan2
- HAGH | c.870G>A p.V290= | Silent (SNP) | VAF 53/217 reads (24%) | called by muse, mutect2, varscan2
- ITGA7 | c.3501T>C p.H1167= (on ENST00000555728; = p.H1123= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- LRFN2 | c.873C>T p.I291= | Silent (SNP) | VAF 33/261 reads (13%) | called by muse, mutect2, varscan2
- MFSD4A | c.525G>A p.T175= | Silent (SNP) | VAF 482/1045 reads (46%) | catalogued as rs757538864; called by muse, mutect2, varscan2
- MSLN | c.453G>A p.L151= | Silent (SNP) | VAF 71/246 reads (29%) | called by muse, mutect2, varscan2
- MTMR4 | c.3105G>A p.E1035= | Silent (SNP) | VAF 26/420 reads (6%) | called by muse, mutect2
- NAF1 | c.1185C>T p.F395= | Silent (SNP) | VAF 34/316 reads (11%) | called by muse, mutect2
- NAT10 | c.57T>C p.A19= | Silent (SNP) | VAF 46/133 reads (35%) | called by muse, mutect2, varscan2
- OR10S1 | c.543C>G p.L181= | Silent (SNP) | VAF 40/283 reads (14%) | catalogued as rs1344670612, COSV73343081; called by muse, mutect2, varscan2
- OXR1 | c.1152C>G p.V384= (on ENST00000442977 / NM_001198532.1; = p.V383= on NM_018002.3) | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.258G>A p.V86= | Silent (SNP) | VAF 32/672 reads (5%) | called by muse, mutect2
- PGLS | c.246C>T p.L82= | Silent (SNP) | VAF 20/420 reads (5%) | catalogued as rs967170259; called by muse, mutect2
- PLA2G4A | c.1095C>T p.P365= | Silent (SNP) | VAF 110/270 reads (41%) | catalogued as rs763504723, COSV66552337; called by muse, mutect2, varscan2
- PTPRF | c.2754C>T p.F918= | Silent (SNP) | VAF 146/700 reads (21%) | catalogued as COSV63442817; called by muse, mutect2, varscan2
- PXDNL | c.1950G>A p.P650= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs370191695, COSV100686265; called by muse, mutect2, varscan2
- STARD9 | c.2250C>A p.L750= | Silent (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- STC1 | c.579C>G p.L193= | Silent (SNP) | VAF 17/362 reads (5%) | called by muse, mutect2
- TMC2 | c.324G>A p.Q108= | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as rs1217865145; called by muse, mutect2
- TRAV8-6 | c.153T>C p.Y51= | Silent (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- WDR87 | c.357C>T p.D119= | Silent (SNP) | VAF 28/684 reads (4%) | called by muse, mutect2
- YES1 | c.864C>T p.F288= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs769766379, COSV58850880; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851497 T>C | 3'Flank (SNP) | VAF 75/657 reads (11%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.1443+1324G>C | Intron (SNP) | VAF 17/272 reads (6%) | called by muse, mutect2
- CLCN2 | c.1326+48C>G | Intron (SNP) | VAF 22/358 reads (6%) | called by muse, mutect2
- CLEC16A | c.2642-9792G>C | Intron (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- CTSA | c.-34C>T | 5'UTR (SNP) | VAF 32/179 reads (18%) | catalogued as rs771295717, COSV51944344; called by muse, mutect2, varscan2
- DDIT4 | c.-38T>C | 5'UTR (SNP) | VAF 62/347 reads (18%) | called by muse, mutect2, varscan2
- EML1 | c.68-548G>C | Intron (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- FKBP10 | c.*7G>A | 3'UTR (SNP) | VAF 47/483 reads (10%) | catalogued as rs782184772; called by muse, mutect2
- LINC00934 | n.1630C>T | RNA (SNP) | VAF 16/102 reads (16%) | catalogued as rs1277908346; called by muse, varscan2
- LINC01164 | n.820C>T | RNA (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- PLEKHS1 | c.-43G>C | 5'UTR (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100732778; called by muse, mutect2, varscan2
- SLC7A5P2 | n.303C>G | RNA (SNP) | VAF 64/2286 reads (3%) | called by muse, mutect2
- TBX21 | c.-33C>G | 5'UTR (SNP) | VAF 29/215 reads (13%) | called by muse, mutect2, varscan2
- TPM3 | c.244-6833G>C | Intron (SNP) | VAF 112/973 reads (12%) | called by muse, mutect2, varscan2
